Gene-level copy-number profile of tumor specimen TCGA-AA-A02W-01A from TCGA case TCGA-AA-A02W, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 73.1 years (26,693 days).
Specimen TCGA-AA-A02W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.b7012e03-e41b-4988-975c-f901fc668fbd.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A02W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/946d6c62-faf8-452d-8ce8-5049283ff469

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 1,023; copy number 2: 19,290; copy number 3: 32,783; copy number 4: 971; copy number 5: 2,529; copy number 6: 1,255; copy number 7: 1,825; copy number 8: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A02W-01A-01D-A008-01): tumor purity 0.72, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:18,415,728–18,551,705, 13 genes: KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,840 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:39,522,976–40,172,612, 15 genes, copy number 8 (within-gene range 1–8): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:74,234,700–78,153,913, 37 genes, copy number 7: JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1.
- chr8:84,162,118–89,791,064, 77 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:90,198,389–145,066,685, 885 genes, copy number 7 (within-gene range 6–11) (broad region; genes not listed).
- chr14:105,546,610–106,360,324, 115 genes, copy number 7 (broad region; genes not listed).
- chr20:4,070,152–4,075,165, 1 gene, copy number 7: AL356414.1.

Autosomal genes at a single copy (total copy number 1): 1,023. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
